Somatic mutation profile of tumor specimen TCGA-HC-7212-01A (aliquot TCGA-HC-7212-01A-11D-2114-08) from TCGA case TCGA-HC-7212, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.3 years (20,576 days).
Specimen TCGA-HC-7212-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) defd6e5f-64aa-4a43-9531-b40fc9b49911.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7212-10A (Blood Derived Normal), aliquot TCGA-HC-7212-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/624274dd-da6a-44ba-99bd-3b0fed8baf02

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DLGAP2 | c.2839G>A p.G947S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1190246849, COSV70096504; called by muse, mutect2
- HTR2A | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 5/62 reads (8%) | catalogued as COSV66326961; called by muse, mutect2
- HYAL3 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs142315421; called by muse, mutect2, varscan2
- ITGA2B | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52231977; called by muse, mutect2, varscan2
- KDM6A | c.4005+5_4005+8del p.X1335_splice | Splice Site (DEL) | VAF 13/45 reads (29%) | catalogued as rs886041946; called by pindel, varscan2
- NCOR1 | c.4573C>T p.Q1525* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV51968854; called by muse, mutect2, varscan2
- PRKACA | c.589T>G p.W197G | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV58066592, COSV58067279, COSV58070561; called by muse, mutect2, varscan2
- RASSF7 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60346230; called by muse, mutect2
- RBM41 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52562722; called by muse, mutect2, varscan2
- STON1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs760676566, COSV59128522; called by muse, mutect2, varscan2
- SYCP2 | c.1624A>G p.R542G | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV62767258; called by muse, mutect2, varscan2
- TIFAB | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.031); catalogued as COSV72345742; called by muse, mutect2
- TRIM6 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1238156687, COSV53475234; called by muse, mutect2
- VPS13D | c.2078A>G p.D693G | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV62527492; called by muse, mutect2, varscan2
- WDR37 | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.3); catalogued as COSV54127913; called by muse, mutect2, varscan2
- ZNF79 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV61070685; called by muse, mutect2, varscan2
- PTEN | c.986del p.N329Ifs*15 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- ARPIN | c.456C>T p.L152= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as rs373686419; called by muse, mutect2, varscan2
- OTOP2 | c.798T>C p.G266= | Silent (SNP) | VAF 92/298 reads (31%) | catalogued as COSV58881254; called by muse, mutect2, varscan2
- PTPRJ | c.1524C>A p.G508= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- IGKV1-13 | n.297G>C | RNA (SNP) | VAF 29/285 reads (10%) | called by muse, mutect2, varscan2
